Gene-level copy-number profile of tumor specimen ALCH-B0CQ-TTP1-A from ALCHEMIST case ALCH-B0CQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.3 years (18,732 days).
Specimen ALCH-B0CQ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 66d925af-a690-47f0-a3c1-4de09f56dfc6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0CQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/789eb2cb-eedd-4880-b86f-277f52bca454

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 105; copy number 1: 8,695; copy number 2: 44,281; copy number 3: 4,552; copy number 4: 575; copy number 5: 174; copy number 6: 7; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 103 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:110,517,217–110,519,175, 1 gene: KCNA10.
- chr3:141,115,124–141,124,182, 1 gene (within-gene range 0–1): AC108727.2.
- chr7:66,505,155–66,592,397, 4 genes (within-gene range 0–2): AC008267.1, AC008267.3, AC006001.3, AC006001.4.
- chr9:63,703,065–63,703,755, 1 gene: AL591438.2.
- chr9:64,621,560–64,765,535, 5 genes: AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr9:128,371,361–128,437,351, 6 genes: URM1, AL359091.1, MIR219A2, MIR219B, CERCAM, AL359091.4.
- chr9:130,902,438–130,945,520, 2 genes: FIBCD1, AL161733.1.
- chr9:132,582,606–132,590,252, 1 gene: BARHL1.
- chr14:100,587,775–100,589,326, 1 gene: AL163974.1.
- chr15:25,180,497–25,225,284, 25 genes (within-gene range 0–1): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:75,674,322–75,712,848, 3 genes (within-gene range 0–2): CSPG4, AC105020.4, AC105020.1.
- chr15:76,174,891–76,181,486, 1 gene (within-gene range 0–1): AC091100.1.
- chr15:76,993,359–77,037,475, 1 gene: PSTPIP1.
- chr15:99,416,584–99,435,160, 2 genes: AC015660.3, AC015660.1.
- chr16:56,351,886–56,353,524, 1 gene (within-gene range 0–2): AC009102.2.
- chr18:8,471,831–8,472,128, 1 gene: RN7SL50P.
- chr18:79,395,856–79,529,325, 6 genes (within-gene range 0–1): NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2.
- chr19:10,304,803–10,336,248, 6 genes (within-gene range 0–2): ZGLP1, AC011511.1, FDX2, AC011511.4, RAVER1, AC114271.1.
- chr19:48,968,130–49,024,333, 6 genes (within-gene range 0–1): GYS1, RUVBL2, MIR6798, LHB, AC008687.4, CGB3.
- chr21:7,744,962–8,454,792, 26 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.
- chr22:20,129,456–20,151,055, 2 genes: ZDHHC8, CCDC188.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 182 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:218,200,434–218,201,388, 1 gene, copy number 5: HMGB1P9.
- chr9:64,817,870–64,836,341, 1 gene, copy number 5: AL359955.1.
- chr9:65,189,995–65,230,861, 3 genes, copy number 6: BMS1P12, AL512605.1, AL512605.2.
- chr14:33,924,227–40,390,547, 121 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:62,604,113–64,944,591, 50 genes, copy number 5 (within-gene range 4–5): ATP5F1AP4, KCNH5, AL137191.1, PARP1P2, RHOJ, AL049871.1, GPHB5, PPP2R5E, AL132992.1, AL136038.3, AL136038.1, GCATP1, WDR89, AL136038.2, HSPE1P2, RNU6-597P, Y_RNA, RNU6-1162P, AL136038.4, U3, SGPP1, EIF2S2P1, RNU7-116P, SYNE2, AL161670.1, RPS28P1, Y_RNA, ESR2, MIR548H1, AL161756.1, TEX21P, AL161756.3, AL161756.2, MTHFD1, AL122035.1, AL122035.2, ZBTB25, AKAP5, ZBTB1, AL049869.2, AL049869.3, HSPA2, PPP1R36, AL049869.1, NUP50P1, PLEKHG3, SPTB, MIR7855, RPPH1-2P, CHURC1.
- chr14:64,939,152–64,942,905, 1 gene, copy number 5 (within-gene range 4–5): GPX2.
- chr14:104,857,792–104,858,836, 1 gene, copy number 6: AL583810.1.
- chr19:29,811,991–29,824,312, 1 gene, copy number 7: CCNE1.
- chr22:20,338,805–20,354,387, 3 genes, copy number 6 (within-gene range 1–6): FAM230G, AC007731.2, AC007731.5.

Autosomal genes at a single copy (total copy number 1): 6,361. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
